Somatic mutation profile of tumor specimen MP2PRT-PAPUWP-TMP1-A (aliquot MP2PRT-PAPUWP-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPUWP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.1 years (420 days).
Specimen MP2PRT-PAPUWP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55640a7b-eb03-42de-a9bc-6c3501737cd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPUWP-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPUWP-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/520f01d7-451b-4e3c-869d-d5e0fc764b42

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPRIN2 | c.1993A>G p.K665E | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.031); catalogued as rs1362668202; called by muse, mutect2, varscan2
- KIAA1109 | c.2711C>G p.P904R | Missense Mutation (SNP) | VAF 39/383 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs200350460, COSV52674260; called by muse, mutect2, varscan2
- SLC52A1 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.433); catalogued as rs150164483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN1 | c.6865T>G p.C2289G | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
